CCDI case PBCFUG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/e194a79a-b41e-47cd-8789-96638991b594

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Desmoplastic small round cell tumor: ICD-O-3 morphology code: 8806/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 20.8 years (7,599 days).

Biospecimens (3 samples)
- Sample 0DRRTR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRRTZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRRUH: Tissue type: Tumor; Specimen type: Solid Tissue.
